CCDI case PBCVPL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/bf510925-ec4b-42a5-b5fe-fd36a86ba90f

Demographics
Sex at birth: female.

Biospecimens (3 samples)
- Sample 0E1FGI: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0E1FGQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0E1FGU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
